Somatic mutation profile of tumor specimen MP2PRT-PANXKZ-TMP1-A (aliquot MP2PRT-PANXKZ-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANXKZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,271 days).
Specimen MP2PRT-PANXKZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc43456f-368e-4ca3-b2d4-aaa8c68979f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANXKZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANXKZ-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5c9ce60-c4fd-4e2f-ae6d-9f9f6adf8c6a

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ROS1 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745334216, COSV63856729, COSV63857934; called by muse, mutect2, varscan2
- USH2A | c.15307G>A p.D5103N | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs112958319; called by muse, mutect2, varscan2
- ZNF831 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 40/526 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs992393984; called by muse, mutect2
- AC005324.2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 299/652 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ARL1 | c.74T>G p.L25* | Nonsense Mutation (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- CHI3L1 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 185/462 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GLMN | c.478_479insACC p.V159_P160insH | In Frame Ins (INS) | VAF 61/169 reads (36%) | called by mutect2, pindel, varscan2
- HEXD | c.1206G>C p.K402N (on ENST00000327949 / NM_001369487.1; = p.S432T on NM_173620.3) | Missense Mutation (SNP) | VAF 222/528 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714649 TGACACTCTCAGGATGTGGGTTTTCACACTGTGTCTCTCGCACAGTA>GGGG | Missense Mutation (DEL) | VAF 60/74 reads (81%) | called by pindel, varscan2*
- TENM2 | c.6223C>G p.Q2075E (on ENST00000518659 / NM_001122679.2; = p.Q1836E on NM_001080428.3) | Missense Mutation (SNP) | VAF 225/528 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DUOX1 | c.1734G>A p.A578= | Silent (SNP) | VAF 227/572 reads (40%) | catalogued as rs138680195; called by muse, mutect2, varscan2
- MYEOV | c.345C>T p.A115= | Silent (SNP) | VAF 253/598 reads (42%) | called by muse, mutect2, varscan2
